Gene-level copy-number profile of tumor specimen TCGA-2G-AAEV-01A from TCGA case TCGA-2G-AAEV, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 34.7 years (12,673 days).
Specimen TCGA-2G-AAEV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 820c4c99-fef4-409e-8d10-847774006327.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAEV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/c5c3e354-b8ca-4011-8319-460f0a34e63f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 572; copy number 2: 19,655; copy number 3: 21,303; copy number 4: 11,053; copy number 5: 2,757; copy number 6: 1,962; copy number 7: 349; copy number 8: 342; copy number 9: 446; copy number 11: 201; copy number 15: 243.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–2): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr5:710,355–850,986, 4 genes (within-gene range 0–2): ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3.
- chr15:21,927,657–22,095,857, 11 genes (within-gene range 0–5): NF1P2, MIR5701-3, OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,581 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:162,322,188–189,709,714, 344 genes, copy number 7 (broad region; genes not listed).
- chr8:65,644,734–65,771,261, 2 genes, copy number 7 (within-gene range 6–7): MTFR1, AC055822.1.
- chr8:69,942,948–70,071,693, 3 genes, copy number 7: SDCBPP2, SUMO2P20, PRDM14.
- chr12:66,767–32,993,754, 813 genes, copy number 8–15 (broad region; genes not listed).
- chr12:37,575,587–47,782,751, 147 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr16:64,364,781–71,727,992, 272 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 60. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
